Somatic mutation profile of tumor specimen MBCProject_3602_T2_WES (aliquot MBCProject_3602_T2_WES_1) from CMI case MBCProject_3602, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and mucinous carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 42.7 years (15,600 days).
Specimen MBCProject_3602_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 537decbc-5ce1-49a3-a876-d7b5d1d88f2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_3602_SALIVA (Saliva), aliquot MBCProject_3602_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f4a7a1a-db80-4d73-8e6c-f85968c76e0a

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 9, Frame Shift Del 3, 3'UTR 2, Nonsense Mutation 2, Frame Shift Ins 2, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP23 | c.404G>C p.R135P | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55687284; called by muse, mutect2, varscan2
- ATP9A | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773916795, COSV100125076; called by muse, mutect2, varscan2
- BABAM1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.105); catalogued as rs1378872301, COSV63921743; called by muse, mutect2, varscan2
- CAMTA1 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs376910869, COSV57922945; called by muse, mutect2, varscan2
- CASZ1 | c.4127C>T p.S1376F | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as COSV100681512; called by muse, mutect2, varscan2
- CFAP221 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs200060056, COSV54656270; called by muse, mutect2, varscan2
- DIP2C | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 140/483 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV99793480; called by muse, mutect2, varscan2
- HDAC6 | c.2930G>T p.G977V | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV61929878; called by muse, mutect2, varscan2
- MICA | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as rs376912874, COSV69826408; called by muse, mutect2
- PKN2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 61/218 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as rs540999973, COSV60135353; called by muse, mutect2, varscan2
- POTEH | c.558G>T p.W186C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as rs1418357120, COSV100625036; called by mutect2, varscan2
- PTGER2 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as rs745828156; called by muse, mutect2, varscan2
- PYGO1 | c.832C>T p.R278* | Nonsense Mutation (SNP) | VAF 66/226 reads (29%) | catalogued as COSV57346659; called by muse, mutect2, varscan2
- RBMS2 | c.978C>A p.D326E | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as COSV100008665; called by muse, mutect2, varscan2
- TTLL8 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 55/101 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.251); catalogued as rs768783873; called by muse, mutect2, varscan2
- ZMAT1 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as rs1183125656; called by muse, mutect2, varscan2
- CLEC5A | c.143C>G p.S48* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- CPSF2 | c.1661A>G p.N554S | Missense Mutation (SNP) | VAF 87/390 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ENTPD7 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 62/250 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- FAM167B | c.281A>T p.D94V | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GATA3 | c.1251dup p.T418Hfs*89 | Frame Shift Ins (INS) | VAF 85/308 reads (28%) | called by mutect2, pindel, varscan2
- GBGT1 | c.965A>G p.D322G | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- GIMAP8 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2
- GON4L | c.269del p.P90Qfs*3 | Frame Shift Del (DEL) | VAF 79/408 reads (19%) | called by mutect2, pindel*, varscan2
- MARCHF7 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.989); called by muse, mutect2
- MUC16 | c.10961C>A p.T3654K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- NCOR2 | c.4902dup p.T1635Hfs*54 | Frame Shift Ins (INS) | VAF 50/166 reads (30%) | called by mutect2, pindel, varscan2
- NPAS3 | c.324C>A p.N108K (on ENST00000356141 / NM_001164749.2; = p.N78K on NM_022123.3) | Missense Mutation (SNP) | VAF 17/433 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.076); called by muse, mutect2
- OR13C3 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2
- SLC35B2 | c.226del p.L76Wfs*2 | Frame Shift Del (DEL) | VAF 108/446 reads (24%) | called by mutect2, pindel, varscan2
- SLC35C1 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- SLC4A7 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SLC6A3 | c.539G>C p.C180S | Missense Mutation (SNP) | VAF 145/1335 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- SRCIN1 | c.1039C>T p.P347S (on ENST00000621492; = p.P313S on NM_025248.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- STAP2 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 49/236 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STAU2 | c.369T>A p.N123K (on ENST00000524300 / NM_001164380.2; = p.N91K on NM_014393.2) | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- SYN1 | c.299G>A p.G100D | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- USP34 | c.2624T>G p.L875R | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF441 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- ZNF469 | c.3836del p.G1279Afs*248 (on ENST00000437464; = p.G1307Afs*248 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 36/173 reads (21%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.1644C>T p.Y548= (on ENST00000392017 / NM_030803.7; = p.Y529= on NM_017974.4) | Silent (SNP) | VAF 132/376 reads (35%) | catalogued as rs777423380, COSV61469167; called by muse, mutect2, varscan2
- BTBD17 | c.759C>T p.R253= | Silent (SNP) | VAF 34/276 reads (12%) | catalogued as COSV100945376; called by muse, mutect2, varscan2
- DEPTOR | c.96G>A p.E32= | Silent (SNP) | VAF 25/515 reads (5%) | called by muse, mutect2
- GLYATL1 | c.324A>G p.E108= (on ENST00000317391 / NM_001354699.1; = p.E139= on NM_080661.4) | Silent (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.954T>A p.P318= | Silent (SNP) | VAF 22/805 reads (3%) | called by muse, mutect2
- LZTS2 | c.765G>T p.G255= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as rs1230492028; called by muse, mutect2, varscan2
- NRXN2 | c.465C>T p.I155= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- PNKP | c.1065C>G p.P355= | Silent (SNP) | VAF 117/357 reads (33%) | catalogued as rs569834947; called by muse, mutect2, varscan2
- ZNF496 | c.885C>T p.S295= | Silent (SNP) | VAF 27/282 reads (10%) | called by muse, mutect2
- CHIT1 | c.*652C>A | 3'UTR (SNP) | VAF 125/619 reads (20%) | called by muse, mutect2, varscan2
- LINC01036 | n.171C>G | RNA (SNP) | VAF 57/332 reads (17%) | called by muse, mutect2, varscan2
- RYR2 | c.11146-1185G>C | Intron (SNP) | VAF 27/224 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.*21C>A | 3'UTR (SNP) | VAF 29/112 reads (26%) | called by muse, mutect2, varscan2
